Somatic mutation profile of tumor specimen TCGA-EE-A181-06A (aliquot TCGA-EE-A181-06A-11D-A196-08) from TCGA case TCGA-EE-A181, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 84.9 years (30,995 days).
Specimen TCGA-EE-A181-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ebd8773a-206e-4d5a-b55f-ac4f0b132d93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A181-10A (Blood Derived Normal), aliquot TCGA-EE-A181-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0a1767a-0748-404c-8eb8-dfe53531e26f

The open-access MAF lists 3,231 somatic variants for this specimen: 2,086 protein-altering or splice-affecting, 1,072 silent, 73 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,936, Silent 1,072, Nonsense Mutation 91, Intron 36, Splice Site 26, RNA 23, Splice Region 19, 3'UTR 7, Frame Shift Del 5, Frame Shift Ins 5, 5'Flank 3, In Frame Del 2.

Variants (750 of 3,231; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.22C>T p.R8* | Nonsense Mutation (SNP) | VAF 26/76 reads (34%) | catalogued as rs886043986, COSV55597437; ClinVar: pathogenic; called by mutect2, varscan2
- ARID1B | c.3496C>T p.Q1166* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as rs1554231904, COSV51666413; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BCL6 | c.1852C>T p.R618C | Missense Mutation (SNP) | VAF 5/40 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs867576130, COSV51651017; called by mutect2, varscan2
- BTK | c.1766A>G p.E589G | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs128621206, CD095368, CM940204, COSV58124478; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.249C>G p.H83Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs34968276, CM056553, CM165739, COSV58684711, COSV58719805; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DNMT3B | c.2452G>A p.V818M | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121908940, CM992876, COSV52419526; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- GPC3 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | catalogued as rs104894855, CM001185, COSV63668697; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KIF5A | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387907289, CM126271, COSV54060211; ClinVar: pathogenic; called by muse, varscan2
- KNSTRN | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 6/38 reads (16%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as rs868438023, COSV51103508; ClinVar: likely pathogenic; called by mutect2, varscan2
- OXA1L | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 16/77 reads (21%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.11); PolyPhen benign (0.208); catalogued as rs773412250, COSV53536555; called by muse, mutect2, varscan2
- PDPK1 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 30/102 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs1263044277, COSV51913046; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 33/235 reads (14%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- SCN4A | c.2014C>T p.R672C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs80338785, CM004139, CM013034, CM042771, COSV71129656; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.428T>A p.V143E | Missense Mutation (SNP) | VAF 28/39 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1511132, COSV52737174, COSV52760297, COSV52868891; called by muse, mutect2, varscan2
- TSC1 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | catalogued as rs118203434, CM981932, COSV53763655, COSV53766104; ClinVar: pathogenic; called by mutect2, varscan2
- TUBB8 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs869025272, CM160731, COSV100226026; ClinVar: pathogenic; called by mutect2, varscan2
- A2M | c.3157C>T p.R1053* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as rs1232878525, COSV59394009; called by mutect2, varscan2
- AAAS | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV99267034; called by muse, mutect2, varscan2
- AADAT | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as rs777046313, COSV61788319; called by muse, varscan2
- ABCA12 | c.1759C>T p.P587S (on ENST00000272895 / NM_173076.3; = p.P269S on NM_015657.3) | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.069); catalogued as COSV55959609; called by muse, mutect2, varscan2
- ABCA3 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.823); catalogued as COSV57055137; called by muse, mutect2, varscan2
- ABCA4 | c.1357-1G>A p.X453_splice | Splice Site (SNP) | VAF 20/70 reads (29%) | catalogued as COSV64679608; called by muse, mutect2, varscan2
- ABCA6 | c.2668G>A p.E890K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.022); catalogued as rs781249897, COSV52638284; called by mutect2, varscan2
- ABCA8 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV52198867; called by muse, mutect2, varscan2
- ABCA8 | c.96+1G>A p.X32_splice | Splice Site (SNP) | VAF 13/86 reads (15%) | catalogued as rs866043934, COSV52214880; called by muse, varscan2
- ABCB1 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.398); catalogued as COSV55948262, COSV55956281, COSV55966191; called by muse, mutect2, varscan2
- ABCB11 | c.2771G>A p.G924E | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55598143; called by muse, mutect2, varscan2
- ABCB5 | c.1760G>A p.R587Q (on ENST00000404938 / NM_001163941.2; = p.R142Q on NM_178559.6) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs755832012, COSV51702431; called by mutect2, varscan2
- ABCB5 | c.2272G>T p.G758C (on ENST00000404938 / NM_001163941.2; = p.G313C on NM_178559.6) | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs373783857, COSV51723348, COSV99327421; called by muse, mutect2, varscan2
- ABCC11 | c.296G>A p.W99* | Nonsense Mutation (SNP) | VAF 14/58 reads (24%) | catalogued as COSV62326502; called by muse, varscan2
- ABCC8 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT tolerated (0.79); PolyPhen benign (0.013); catalogued as rs1448146101, COSV56850824; called by muse, varscan2
- ABCG2 | c.1253A>T p.N418I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV52950407; called by muse, mutect2
- ABLIM1 | c.1219G>C p.E407Q | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.186); catalogued as COSV53318194; called by muse, mutect2, varscan2
- ABLIM3 | c.1123G>A p.G375R | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV58650042; called by muse, mutect2, varscan2
- ABRA | c.83G>A p.S28N | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV61733893; called by muse, mutect2, varscan2
- ABTB1 | c.832G>A p.V278M (on ENST00000232744 / NM_172027.3; = p.V136M on NM_032548.3) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51743253; called by muse, mutect2, varscan2
- AC023055.1 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.629); catalogued as rs544589772, COSV60242962; called by mutect2, varscan2
- AC023055.1 | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.754); catalogued as rs1565679652, COSV60244879; called by muse, mutect2, varscan2
- ACAN | c.2879G>A p.G960E | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV61371471; called by muse, varscan2
- ACAN | c.4270C>T p.P1424S | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.076); catalogued as rs764734177, COSV61359547; called by muse, varscan2
- ACAP1 | c.1132G>A p.G378S | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50144657; called by muse, mutect2, varscan2
- ACE | c.3282-1G>A p.X1094_splice | Splice Site (SNP) | VAF 9/35 reads (26%) | catalogued as COSV52014678; called by muse, mutect2, varscan2
- ACLY | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); catalogued as COSV61253845; called by muse, mutect2, varscan2
- ACOT12 | c.1592C>T p.S531F | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs750383961, COSV56898964; called by muse, mutect2, varscan2
- ACOXL | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV61332044; called by muse, varscan2
- ACP7 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV100488544; called by muse, mutect2, varscan2
- ACSM2A | c.967C>T p.L323F (on ENST00000219054; = p.L244F on NM_001308169.2) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV54591095; called by muse, mutect2, varscan2
- ACSM4 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV68067891, COSV68069762; called by muse, mutect2, varscan2
- ACSM6 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.326); catalogued as COSV58977705; called by muse, mutect2, varscan2
- ACTG1 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.987); catalogued as COSV59512409; called by muse, mutect2, varscan2
- ACTL8 | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64862966; called by muse, mutect2, varscan2
- ACTR3B | c.368G>A p.R123K | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99754225; called by muse, varscan2
- ACTRT2 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65760753; called by muse, varscan2
- ADA2 | c.998C>T p.S333F (on ENST00000262607; = p.S92F on NM_177405.3) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV52834582; called by muse, mutect2, varscan2
- ADA2 | c.629T>A p.I210N | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs376482971, COSV52834607; called by mutect2, varscan2
- ADAM11 | c.1724G>A p.G575E | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52350508, COSV99567428; called by muse, mutect2, varscan2
- ADAM12 | c.926T>C p.V309A | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV64116378; called by muse, mutect2, varscan2
- ADAM18 | c.345-1G>A p.X115_splice | Splice Site (SNP) | VAF 10/65 reads (15%) | catalogued as COSV55856869; called by muse, mutect2, varscan2
- ADAM19 | c.1649C>T p.T550I | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.179); catalogued as COSV99977042; called by muse, varscan2
- ADAM19 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV57426604; called by mutect2, varscan2
- ADAM28 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1303422157, COSV56099428, COSV56099824; called by mutect2, varscan2
- ADAM28 | c.1709C>T p.S570L | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as rs201643797; called by mutect2, varscan2
- ADAM32 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.27); catalogued as rs771061077, COSV65947256, COSV65954266; called by muse, varscan2
- ADAM9 | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV65959854; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs372619362; called by mutect2, varscan2
- ADAMTS20 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1216030314, COSV101239668; called by muse, mutect2, varscan2
- ADAMTS20 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67130026; called by muse, varscan2
- ADAR | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); catalogued as COSV52722565; called by muse, mutect2, varscan2
- ADCY1 | c.1315C>T p.H439Y | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52040303; called by mutect2, varscan2
- ADCY1 | c.2807C>T p.S936L | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.018); catalogued as rs750651163, COSV52033917, COSV99812419; called by mutect2, varscan2
- ADCY5 | c.1246C>T p.Q416* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as rs1553733582, COSV59205840; called by muse, mutect2, varscan2
- ADCY8 | c.3488G>A p.G1163E | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267601769, COSV53899204; called by mutect2, varscan2
- ADCYAP1 | c.97T>C p.F33L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV52487640; called by muse, mutect2
- ADD1 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.661); catalogued as COSV53275640; called by muse, mutect2, varscan2
- ADGRB3 | c.2128C>T p.P710S | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV65419105; called by muse, mutect2, varscan2
- ADGRF2 | c.583T>C p.S195P (on ENST00000296862 / NM_001368115.2; = p.S127P on NM_153839.7) | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as COSV57292935; called by muse, mutect2
- ADGRF2 | c.1006C>T p.P336S (on ENST00000296862 / NM_001368115.2; = p.P268S on NM_153839.7) | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as COSV57292950; called by muse, mutect2, varscan2
- ADGRF2 | c.1794G>A p.W598* (on ENST00000296862 / NM_001368115.2; = p.W530* on NM_153839.7) | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as COSV57292968; called by muse, varscan2
- ADGRF5 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs774164965, COSV51942363; called by muse, varscan2
- ADGRF5 | c.14G>A p.R5K | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV99345921; called by muse, varscan2
- ADGRG1 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV65635703, COSV65636800; called by muse, varscan2
- ADGRG4 | c.5951C>T p.P1984L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV54969651; called by muse, mutect2, varscan2
- ADGRL2 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV54671151, COSV54694588; called by muse, mutect2, varscan2
- ADGRL4 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs1227839219, COSV100875687, COSV66067156; called by muse, mutect2, varscan2
- ADGRV1 | c.8662C>T p.P2888S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as rs775159319, COSV67997159; called by mutect2, varscan2
- ADH1C | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1005267020, COSV72463393; called by mutect2, varscan2
- ADH4 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as rs139053416, COSV55500780; called by muse, mutect2, varscan2
- ADTRP | c.80A>T p.E27V | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.023); catalogued as COSV57646539; called by muse, varscan2
- AFF3 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.924); catalogued as rs751422700, COSV57848826; called by mutect2, varscan2
- AGBL5 | c.1564G>A p.G522R | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59938826; called by muse, mutect2, varscan2
- AGL | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV54060219; called by muse, mutect2, varscan2
- AGL | c.3568C>T p.P1190S | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.686); catalogued as COSV54060228; called by muse, mutect2, varscan2
- AGO2 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as COSV55045504; called by muse, mutect2
- AGT | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs147355405, COSV64185672; called by muse, mutect2, varscan2
- AIDA | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.414); catalogued as rs1459203384, COSV60666205; called by muse, mutect2, varscan2
- AIMP2 | c.648C>A p.F216L | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV52244271; called by mutect2, varscan2
- AKAP1 | c.740A>T p.K247M | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.38); catalogued as COSV58473579; called by mutect2, varscan2
- AKAP11 | c.3619C>T p.L1207F | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV50305526; called by muse, mutect2, varscan2
- AKAP17A | c.764T>C p.V255A | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV58312517; called by muse, mutect2, varscan2
- AKAP3 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748232602, COSV57421547; called by mutect2, varscan2
- AKAP9 | c.3922C>T p.H1308Y | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV62360035; called by muse, mutect2, varscan2
- AKR1C2 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as COSV66334675; called by muse, mutect2, varscan2
- AKR1D1 | c.939-1G>A p.X313_splice | Splice Site (SNP) | VAF 26/203 reads (13%) | catalogued as COSV54341579; called by muse, mutect2, varscan2
- AL645922.1 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.999); catalogued as COSV54963061; called by muse, mutect2, varscan2
- ALDH1A2 | c.1474G>A p.G492R | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868060815, COSV51079166; called by mutect2, varscan2
- ALDH5A1 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62373442, COSV62374719; called by muse, varscan2
- ALMS1 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as rs867586310, COSV52505548; called by mutect2, varscan2
- ALOX5 | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs757213685, COSV65555149; called by mutect2, varscan2
- ALPK2 | c.4094G>C p.G1365A | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.025); catalogued as COSV64498370; called by muse, mutect2, varscan2
- AMPH | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV57745942; called by muse, mutect2, varscan2
- AMPH | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781682680, COSV57737654; called by mutect2, varscan2
- ANG | c.412C>T p.H138Y | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59013473; called by muse, mutect2, varscan2
- ANK2 | c.3956G>A p.R1319K | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV52194503; called by muse, varscan2
- ANKH | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as COSV52487917; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV51851879; called by mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6328C>T p.P2110S | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.477); catalogued as COSV51861085; called by muse, mutect2, varscan2
- ANKRD10 | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57442550; called by muse, mutect2, varscan2
- ANKRD30A | c.931G>A p.E311K (on ENST00000611781; = p.E255K on NM_052997.2) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.292); catalogued as COSV64620881; called by mutect2, varscan2
- ANKRD35 | c.1429G>A p.G477S | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as rs782504931, COSV62911895; called by muse, mutect2, varscan2
- ANKRD40 | c.400A>G p.T134A | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.117); catalogued as COSV53335343; called by muse, mutect2, varscan2
- ANKRD55 | c.1706C>T p.P569L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV61951611; called by muse, varscan2
- ANO2 | c.1667G>A p.R556Q (on ENST00000356134 / NM_001278597.3; = p.R560Q on NM_001278596.3) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs773771654, COSV59020666; called by mutect2, varscan2
- ANO3 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.927); catalogued as COSV56808188; called by mutect2, varscan2
- ANO4 | c.1396G>A p.E466K (on ENST00000392977 / NM_001286615.2; = p.E431K on NM_178826.4) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV54593435; called by muse, varscan2
- ANO4 | c.1504C>T p.L502F (on ENST00000392977 / NM_001286615.2; = p.L467F on NM_178826.4) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.453); catalogued as COSV54617943; called by muse, varscan2
- ANO4 | c.2315G>A p.G772E (on ENST00000392977 / NM_001286615.2; = p.G737E on NM_178826.4) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as rs866052988, COSV54589756; called by muse, mutect2, varscan2
- ANO6 | c.1139T>C p.V380A | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV57669772; called by muse, mutect2, varscan2
- ANPEP | c.2365C>T p.H789Y | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV55594618; called by muse, varscan2
- ANXA6 | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); catalogued as COSV62908802; called by muse, mutect2, varscan2
- AOC1 | c.1523A>G p.N508S | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as rs1323355007, COSV62871531; called by muse, mutect2, varscan2
- AOX1 | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV65982083; called by muse, varscan2
- AP2A2 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1426464860, COSV59960208, COSV59960590; called by muse, mutect2, varscan2
- APOB | c.10975C>T p.L3659F | Missense Mutation (SNP) | VAF 82/223 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.105); catalogued as COSV51957839; called by muse, varscan2
- APOB | c.6035G>A p.R2012Q | Missense Mutation (SNP) | VAF 117/273 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0.022); catalogued as rs749146264, COSV51931949; ClinVar: likely benign; called by muse, mutect2, varscan2
- APOB | c.4478C>T p.S1493F | Missense Mutation (SNP) | VAF 42/235 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as COSV51957857; called by muse, mutect2, varscan2
- AQR | c.2155C>T p.L719F | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs771802210, COSV50061603; called by mutect2, varscan2
- AREG | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV99144397; called by muse, varscan2
- ARHGAP11A | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1047623150, COSV64380682, COSV64381251; called by muse, mutect2, varscan2
- ARHGAP12 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.251); catalogued as COSV60966996; called by muse, mutect2, varscan2
- ARHGAP20 | c.1340C>T p.S447L | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.234); catalogued as COSV52820955; called by muse, mutect2, varscan2
- ARHGAP21 | c.2467C>T p.P823S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV57612284; called by muse, mutect2, varscan2
- ARHGAP25 | c.373G>A p.G125R (on ENST00000409202 / NM_001007231.3; = p.G118R on NM_014882.3) | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV54903844; called by muse, mutect2, varscan2
- ARHGAP29 | c.3118G>A p.G1040R | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as CM153307, COSV53118255; called by muse, mutect2, varscan2
- ARHGAP32 | c.5390A>T p.D1797V (on ENST00000310343 / NM_001378025.1; = p.D1448V on NM_014715.4) | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59857107; called by muse, mutect2, varscan2
- ARHGAP5 | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.296); catalogued as COSV61533919; called by muse, mutect2, varscan2
- ARHGEF2 | c.521C>T p.S174F (on ENST00000361247 / NM_001162383.2; = p.S147F on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58114840; called by muse, mutect2, varscan2
- ARL4C | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.929); catalogued as COSV60214769; called by muse, varscan2
- ARMC4 | c.3124A>G p.R1042G | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as rs1469966066, COSV59477065; called by muse, mutect2
- ARMC4 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as rs1277766885, COSV53465527; called by muse, mutect2, varscan2
- ARNT2 | c.144C>T p.S48= | Splice Region (SNP) | VAF 12/59 reads (20%) | catalogued as rs768912129, COSV57591570; called by mutect2, varscan2
- ARRB2 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV52619429, COSV99347048; called by muse, mutect2, varscan2
- ARSF | c.698G>A p.W233* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as COSV100839540; called by muse, mutect2, varscan2
- ART4 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as COSV57453607; called by muse, mutect2, varscan2
- AS3MT | c.66G>T p.K22N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.097); catalogued as COSV54919543; called by mutect2, varscan2
- ASAP1 | c.2486C>T p.P829L | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV63055592; called by muse, mutect2, varscan2
- ASAP3 | c.2387C>T p.P796L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV60878774; called by muse, mutect2, varscan2
- ASB15 | c.1565G>A p.R522K | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51930019; called by muse, varscan2
- ASB17 | c.158A>C p.K53T | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.417); catalogued as COSV52412608; called by muse, mutect2, varscan2
- ASB2 | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100279424; called by muse, mutect2, varscan2
- ASB2 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs375831081; called by mutect2, varscan2
- ASB4 | c.559C>T p.L187F | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV57948819; called by muse, mutect2, varscan2
- ASB5 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as rs763945729, COSV56675197; called by mutect2, varscan2
- ASCC3 | c.3986C>T p.P1329L | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64982415; called by muse, mutect2, varscan2
- ASPHD2 | c.239G>A p.R80K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as COSV53221377; called by muse, mutect2, varscan2
- ASPM | c.2824C>T p.R942C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs546095187, COSV54123988; ClinVar: uncertain significance; called by mutect2, varscan2
- ASXL1 | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV60125398; called by muse, mutect2, varscan2
- ASXL2 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55457549; called by muse, mutect2, varscan2
- ATG2A | c.4963T>C p.S1655P | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.143); catalogued as COSV65969197; called by muse, mutect2
- ATG2B | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV63426399; called by muse, varscan2
- ATG9A | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54701823; called by muse, mutect2, varscan2
- ATP13A1 | c.1351C>T p.L451F | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52292406; called by muse, mutect2, varscan2
- ATP13A4 | c.1002G>A p.W334* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as COSV55076640; called by muse, mutect2, varscan2
- ATP13A4 | c.751C>T p.L251F | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55076659; called by muse, mutect2, varscan2
- ATP13A5 | c.2882C>T p.P961L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs867252383, COSV60877086; called by muse, mutect2
- ATP1A2 | c.2644G>A p.G882R | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63406414; called by muse, mutect2, varscan2
- ATP2B4 | c.2273C>T p.P758L | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58185448; called by muse, mutect2, varscan2
- ATP2C2 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372231003; called by mutect2, varscan2
- ATP5F1B | c.329C>T p.T110I | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as COSV56262417; called by muse, varscan2
- ATP5F1C | c.674T>G p.V225G | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59623055, COSV59623207; called by muse, mutect2
- ATP6V0A4 | c.251G>A p.S84N | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.079); catalogued as COSV59481611; called by mutect2, varscan2
- ATP6V1G3 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 34/119 reads (29%) | catalogued as COSV55281133; called by mutect2, varscan2
- ATP8A2 | c.1897G>A p.D633N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV54980460; called by mutect2, varscan2
- ATP8B1 | c.2632G>A p.D878N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV52179630; called by mutect2, varscan2
- ATRIP | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV56498102; called by muse, mutect2, varscan2
- ATRNL1 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV61820108; called by muse, mutect2, varscan2
- AUH | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100342554; called by muse, varscan2
- B4GALNT3 | c.2977C>A p.R993S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as COSV56759269; called by mutect2, varscan2
- BAALC | c.433-1G>A p.X145_splice (on ENST00000297574 / NM_001364874.1; = p.X110_splice on NM_024812.3) | Splice Site (SNP) | VAF 12/65 reads (18%) | catalogued as rs117445972, COSV52565852; called by muse, mutect2, varscan2
- BAHCC1 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV57027231; called by muse, mutect2, varscan2
- BANK1 | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV59851769; called by mutect2, varscan2
- BAZ1A | c.1863T>G p.C621W | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62412496; called by muse, mutect2, varscan2
- BAZ1B | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.142); catalogued as COSV59995015; called by mutect2, varscan2
- BAZ2A | c.271T>G p.C91G | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV51645348; called by muse, varscan2
- BBX | c.2102C>T p.P701L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1271235826, COSV57897161; called by muse, mutect2, varscan2
- BCAR3 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769965474, COSV53077285; called by mutect2, varscan2
- BCAS3 | c.1637G>T p.G546V | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as COSV66784160; called by mutect2, varscan2
- BCAT1 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373461769; called by mutect2, varscan2
- BDP1 | c.4681A>T p.M1561L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV62435898; called by muse, mutect2, varscan2
- BEST3 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs748136001, COSV58307113; called by mutect2, varscan2
- BFSP1 | c.1436A>G p.Y479C | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV64902377; called by muse, mutect2, varscan2
- BICC1 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54063782; called by muse, varscan2
- BIVM-ERCC5 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV57280197; called by muse, mutect2, varscan2
- BMP2K | c.2941C>T p.R981C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1335782363, COSV55009947; called by mutect2, varscan2
- BMP5 | c.1029T>A p.D343E | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV63701125, COSV63707406; called by muse, varscan2
- BPI | c.593G>A p.R198Q (on ENST00000262865; = p.R194Q on NM_001725.3) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.113); catalogued as rs749629986, COSV53404895, COSV53408318; called by mutect2, varscan2
- BPIFB6 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.783); catalogued as COSV62757017; called by muse, mutect2, varscan2
- BRAF | c.1520C>T p.S507L (on ENST00000288602 / NM_001374244.1; = p.S467L on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); catalogued as rs867748453, COSV56106484; called by mutect2, varscan2
- BRD7 | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs772936465, COSV54271736; called by muse, varscan2
- BRD7 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67160359; called by muse, mutect2, varscan2
- BRDT | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.031); catalogued as COSV62863825; called by muse, mutect2, varscan2
- BRINP1 | c.1870C>T p.R624W | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs369869809; called by mutect2, varscan2
- BRINP1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.037); catalogued as COSV56296410, COSV56304407; called by muse, mutect2, varscan2
- BRINP2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV64180980; called by muse, mutect2, varscan2
- BSN | c.8975A>G p.K2992R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV56530052; called by muse, mutect2, varscan2
- BSN | c.10168C>T p.P3390S | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs767551250, COSV56530061; called by muse, varscan2
- BTN3A3 | c.1372C>T p.P458S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55074241; called by muse, mutect2, varscan2
- BTRC | c.473C>T p.S158F (on ENST00000370187 / NM_033637.4; = p.S122F on NM_003939.5) | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV64563715; called by muse, mutect2, varscan2
- BUB1B | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | catalogued as COSV55017828; called by muse, mutect2
- BUB1B | c.1894C>T p.P632S | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV55017843; called by muse, mutect2, varscan2
- BUB1B | c.2690C>T p.P897L | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV55017861; called by muse, mutect2, varscan2
- C10orf120 | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 66/202 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61492897; called by muse, varscan2
- C10orf120 | c.177-1G>A p.X59_splice | Splice Site (SNP) | VAF 4/26 reads (15%) | catalogued as COSV61492904; called by mutect2, varscan2
- C10orf71 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV60514879; called by muse, varscan2
- C11orf24 | c.1303C>T p.Q435* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV58506808; called by mutect2, varscan2
- C12orf4 | c.707A>G p.N236S | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.192); catalogued as COSV54210606; called by muse, mutect2, varscan2
- C15orf39 | c.2093C>T p.P698L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV62298590; called by muse, mutect2, varscan2
- C1GALT1 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV99777604; called by muse, mutect2, varscan2
- C1GALT1 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV99777606; called by mutect2, varscan2
- C1RL | c.1146G>A p.M382I | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as COSV56927172; called by muse, mutect2, varscan2
- C1S | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.348); catalogued as COSV61070378; called by muse, mutect2, varscan2
- C1orf141 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1356702901, COSV63993516; called by muse, mutect2, varscan2
- C1orf94 | c.601G>A p.D201N (on ENST00000488417 / NM_001134734.2; = p.D11N on NM_032884.5) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as COSV64916191; called by mutect2, varscan2
- C22orf23 | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.691); catalogued as COSV50778892; called by muse, varscan2
- C2CD2 | c.1421C>T p.S474F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV61600852; called by muse, mutect2, varscan2
- C2CD6 | c.26G>A p.R9K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV53801743; called by muse, mutect2, varscan2
- C2orf15 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.027); catalogued as COSV56781666, COSV56782206; called by muse, mutect2, varscan2
- C2orf78 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1048011563, COSV68519682; called by muse, mutect2, varscan2
- C3 | c.4280G>A p.R1427K | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.096); catalogued as COSV55582537; called by muse, mutect2, varscan2
- C3AR1 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99368730; called by muse, mutect2
- C3orf20 | c.1440T>A p.N480K | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99514234; called by muse, mutect2, varscan2
- C3orf20 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.147); catalogued as rs751847596, COSV99514235; called by muse, mutect2, varscan2
- C6orf118 | c.936G>A p.E312= | Splice Region (SNP) | VAF 12/40 reads (30%) | catalogued as COSV57820726; called by muse, mutect2, varscan2
- C7 | c.831G>A p.W277* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV57482991; called by muse, mutect2, varscan2
- C7 | c.2351C>T p.A784V | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.19); PolyPhen benign (0.27); catalogued as rs760231611, COSV57482998; called by muse, mutect2, varscan2
- C8orf34 | c.1609G>A p.G537S | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100446675; called by muse, mutect2, varscan2
- C9 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371134723; called by muse, varscan2
- CA5B | c.724T>A p.S242T | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.926); catalogued as COSV59418122; called by muse, mutect2, varscan2
- CAB39 | c.883C>T p.L295F | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99299963; called by muse, mutect2, varscan2
- CACNA1A | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.103); catalogued as rs960396840, COSV100802763; called by muse, mutect2, varscan2
- CACNA1E | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.996); catalogued as COSV62438829; called by muse, mutect2, varscan2
- CACNA1E | c.2702G>A p.G901E | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.19); catalogued as rs868416223, COSV62390434; called by muse, mutect2, varscan2
- CACNA1E | c.3400T>C p.F1134L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV62438860; called by muse, mutect2, varscan2
- CACNA1E | c.6164A>G p.H2055R (on ENST00000367573 / NM_001205293.3; = p.H2012R on NM_000721.4) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV62438906; called by muse, mutect2, varscan2
- CACNA1F | c.5462G>A p.G1821D | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.999); catalogued as rs781961815, COSV59907443; called by muse, varscan2
- CACNA1G | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.374); catalogued as rs771179433; called by mutect2, varscan2
- CACNA1G | c.2282G>A p.G761D | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61742346; called by muse, mutect2, varscan2
- CACNA2D2 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.536); catalogued as rs769033285, COSV56570278; called by mutect2, varscan2
- CACNA2D3 | c.1072G>A p.G358R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55590408; called by muse, mutect2
- CACNA2D3 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777168401, COSV55535703, COSV55590414; called by muse, mutect2, varscan2
- CACNB2 | c.591C>T p.S197= (on ENST00000324631 / NM_201596.3; = p.S142= on NM_000724.4) | Splice Region (SNP) | VAF 6/26 reads (23%) | catalogued as COSV56651818; called by mutect2, varscan2
- CADM1 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100522978, COSV59021349; called by mutect2, varscan2
- CADM3 | c.877G>A p.D293N (on ENST00000368125 / NM_001127173.3; = p.D327N on NM_021189.5) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63687922; called by mutect2, varscan2
- CAGE1 | c.1426G>A p.E476K (on ENST00000512086; = p.E340K on NM_205864.3) | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs866412142, COSV57074675; called by muse, mutect2
- CALB2 | c.700-1G>A p.X234_splice | Splice Site (SNP) | VAF 18/91 reads (20%) | catalogued as COSV100226460, COSV56942834; called by muse, mutect2, varscan2
- CALCR | c.778C>T p.L260F (on ENST00000649521 / NM_001164737.2; = p.L244F on NM_001742.4) | Missense Mutation (SNP) | VAF 45/67 reads (67%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV64013145; called by muse, mutect2, varscan2
- CAMK4 | c.1303G>A p.G435S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs777904792, COSV56686415; called by mutect2, varscan2
- CAMSAP2 | c.3686G>A p.R1229K (on ENST00000236925 / NM_001297707.2; = p.R1218K on NM_203459.3) | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV52679348; called by muse, mutect2, varscan2
- CANT1 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 64/203 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.024); catalogued as COSV56606936; called by muse, mutect2, varscan2
- CAPN15 | c.2635T>C p.F879L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99562606; called by mutect2, varscan2
- CAPN6 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.733); catalogued as COSV60697680; called by muse, mutect2, varscan2
- CASC3 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52866441; called by mutect2, varscan2
- CATSPERB | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.085); catalogued as COSV56437023; called by muse, mutect2, varscan2
- CBFA2T2 | c.1270T>C p.F424L | Missense Mutation (SNP) | VAF 54/259 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV60802433; called by muse, mutect2, varscan2
- CCDC102B | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV100103796, COSV60156942; called by muse, mutect2, varscan2
- CCDC113 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs372103092, COSV54686436; called by muse, mutect2, varscan2
- CCDC125 | c.1394C>T p.S465F | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.568); catalogued as rs774625160, COSV67289113; called by muse, varscan2
- CCDC138 | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54572813; called by muse, mutect2, varscan2
- CCDC141 | c.3787G>A p.E1263K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.127); catalogued as rs1212530049, COSV55379281; called by muse, mutect2, varscan2
- CCDC144A | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs752415238, COSV61402692; called by mutect2, varscan2
- CCDC15 | c.1106T>C p.V369A | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61085640; called by muse, mutect2, varscan2
- CCDC171 | c.2122C>T p.L708F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs144600578; called by mutect2, varscan2
- CCDC173 | c.1091G>A p.R364K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71654076; called by muse, mutect2, varscan2
- CCDC178 | c.363T>A p.F121L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as COSV55802853; called by muse, mutect2
- CCDC197 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100113677; called by muse, mutect2, varscan2
- CCDC25 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62959825; called by muse, varscan2
- CCDC38 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 36/190 reads (19%) | catalogued as COSV60185444; called by muse, varscan2
- CCDC40 | c.2174G>A p.R725K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.386); catalogued as COSV66479398; called by muse, mutect2, varscan2
- CCDC40 | c.2914A>C p.T972P | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.132); catalogued as COSV66479406; called by muse, mutect2, varscan2
- CCDC88B | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.468); catalogued as COSV57268790; called by muse, varscan2
- CCDC88C | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV66236103; called by mutect2, varscan2
- CCDC93 | c.1571C>T p.T524I | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60125008; called by muse, mutect2, varscan2
- CCER1 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62649044; called by muse, varscan2
- CCKAR | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.155); catalogued as COSV55164636; called by muse, varscan2
- CCL7 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV52337926; called by muse, mutect2, varscan2
- CCN1 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs149037713; called by muse, mutect2, varscan2
- CCNB3 | c.2864C>T p.P955L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV52081209; called by muse, mutect2, varscan2
- CCNB3 | c.3713G>A p.R1238Q | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs1447299051, COSV52072736, COSV52081222; called by mutect2, varscan2
- CCNDBP1 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV55748147; called by muse, mutect2, varscan2
- CCR5 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.473); catalogued as rs764278401, CM104770, COSV52751490; called by muse, mutect2, varscan2
- CCSER1 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61462013, COSV61477981; called by muse, mutect2, varscan2
- CD163 | c.1607G>A p.G536E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63131336; called by muse, mutect2, varscan2
- CD1C | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs116683698, COSV100939410, COSV100939431; called by mutect2, varscan2
- CD1C | c.988C>T p.Q330* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as COSV63807983; called by mutect2, varscan2
- CD1D | c.740G>A p.G247D | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as COSV63810310; called by mutect2, varscan2
- CD1E | c.551G>A p.S184N | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV63771040; called by mutect2, varscan2
- CD2 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.081); catalogued as COSV65645046; called by mutect2, varscan2
- CD22 | c.1867C>A p.P623T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99323427; called by mutect2, varscan2
- CD22 | c.1868C>G p.P623R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99323429; called by muse, mutect2, varscan2
- CD22 | c.2032T>C p.Y678H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV50075186; called by muse, mutect2, varscan2
- CD226 | c.523C>T p.L175F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.9); catalogued as rs760134438, COSV54617039; called by muse, varscan2
- CD244 | c.1070G>A p.R357Q (on ENST00000368033 / NM_001166663.2; = p.R352Q on NM_016382.4) | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201774367; called by mutect2, varscan2
- CD2AP | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 32/295 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs199622885, COSV63763227; called by muse, mutect2, varscan2
- CD36 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373645211; called by muse, mutect2, varscan2
- CD46 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as COSV100522787; called by muse, mutect2, varscan2
- CD5L | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.406); catalogued as rs200057023, COSV63821588; called by muse, mutect2, varscan2
- CD96 | c.365T>A p.L122Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51912783, COSV51924553; called by muse, mutect2, varscan2
- CD96 | c.497A>T p.N166I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51924568; called by muse, mutect2, varscan2
- CDC20B | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57058448; called by mutect2, varscan2
- CDC42EP1 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV50759809; called by muse, varscan2
- CDC73 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV66471068; called by muse, mutect2, varscan2
- CDCA2 | c.1187G>A p.G396E | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57949201; called by muse, mutect2, varscan2
- CDH13 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV51804764; called by mutect2, varscan2
- CDH18 | c.1958A>T p.E653V | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56970996; called by mutect2, varscan2
- CDH2 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 73/110 reads (66%) | SIFT tolerated (0.69); PolyPhen benign (0.071); catalogued as COSV52280880, COSV52299450; called by muse, mutect2, varscan2
- CDH9 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as rs867964392, COSV50259663; called by mutect2, varscan2
- CDK13 | c.1933C>T p.L645F | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1273658762, COSV51707967; called by muse, mutect2, varscan2
- CEACAM1 | c.1130G>A p.G377D | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV50734746; called by muse, mutect2, varscan2
- CEACAM19 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV62552343; called by muse, mutect2, varscan2
- CEACAM20 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 48/252 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780570685, COSV57603704; called by muse, varscan2
- CEACAM20 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.465); catalogued as COSV57603041; called by mutect2, varscan2
- CEACAM6 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.887); catalogued as rs1555821146, COSV52269805; called by muse, mutect2, varscan2
- CECR2 | c.4370C>T p.S1457L (on ENST00000342247 / NM_001290047.2; = p.S1273L on NM_001290046.1) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs536749791, COSV52850513; called by mutect2, varscan2
- CELF4 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100610827, COSV58469327; called by muse, mutect2
- CELSR2 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.534); catalogued as COSV54781000; called by muse, varscan2
- CELSR2 | c.2464G>A p.G822S | Missense Mutation (SNP) | VAF 42/228 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54781014; called by muse, mutect2, varscan2
- CELSR3 | c.805C>A p.P269T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as rs771233173, COSV51181745; called by mutect2, varscan2
- CEMIP2 | c.964C>T p.L322F | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV65485689, COSV65490163; called by muse, varscan2
- CEP104 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139901107, COSV65512136; called by mutect2, varscan2
- CEP126 | c.2683A>C p.T895P | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV54832182; called by muse, mutect2, varscan2
- CEP128 | c.3170C>T p.S1057L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55373449, COSV55393877; called by mutect2, varscan2
- CEP350 | c.728T>G p.M243R | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.054); catalogued as COSV62486294; called by muse, mutect2, varscan2
- CETN1 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.363); catalogued as rs769495541, COSV59121402; called by mutect2, varscan2
- CFAP53 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 48/324 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as rs751078877, COSV68353065; called by mutect2, varscan2
- CFAP54 | c.5947G>A p.E1983K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.06); catalogued as COSV61576150; called by muse, mutect2, varscan2
- CFAP61 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs371793125, COSV55639118; called by mutect2, varscan2
- CFH | c.2993C>T p.A998V | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.937); catalogued as COSV66414959; called by muse, varscan2
- CGNL1 | c.35A>C p.Q12P | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV55577419; called by muse, mutect2, varscan2
- CHAT | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV100340420; called by muse, varscan2
- CHD1L | c.373A>G p.T125A | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV63615610; called by muse, mutect2, varscan2
- CHD3 | c.5087G>A p.G1696E (on ENST00000330494 / NM_001005273.3; = p.G1662E on NM_005852.4) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs1426884513, COSV57881593; called by muse, varscan2
- CHD4 | c.2840C>T p.A947V (on ENST00000357008 / NM_001363606.2; = p.A960V on NM_001273.5) | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV58913117; called by muse, mutect2, varscan2
- CHD6 | c.3176C>T p.S1059L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV58557570, COSV58563525; called by mutect2, varscan2
- CHN1 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.142); catalogued as rs761675174, COSV55035943; called by mutect2, varscan2
- CHRM3 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs750254408, COSV55109415; called by muse, mutect2, varscan2
- CHRNA2 | c.1580G>A p.G527E | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.448); catalogued as COSV53560209; called by muse, mutect2, varscan2
- CHRNA9 | c.1070G>A p.S357N | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV59576589; called by muse, mutect2, varscan2
- CHST11 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57996643; called by muse, mutect2, varscan2
- CIC | c.3311C>T p.S1104F | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.058); catalogued as rs772260824, COSV50668545; called by muse, mutect2, varscan2
- CIT | c.4295C>T p.S1432F | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV55886744; called by muse, varscan2
- CLCN4 | c.1310G>A p.G437D | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.104); catalogued as COSV66466032, COSV66469203; called by muse, mutect2, varscan2
- CLDN2 | c.468G>T p.M156I | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); catalogued as COSV61020890, COSV61021417; called by mutect2, varscan2
- CLEC5A | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69396684; called by muse, mutect2, varscan2
- CLHC1 | c.86G>A p.R29K | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.6); catalogued as COSV68465417; called by muse, varscan2
- CLSPN | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as COSV52058306; called by muse, varscan2
- CLSTN1 | c.1256C>T p.S419F (on ENST00000377298 / NM_001009566.3; = p.S409F on NM_014944.4) | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV63651904; called by muse, mutect2, varscan2
- CLVS2 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.255); catalogued as rs376660185, COSV99033987; called by muse, mutect2, varscan2
- CMPK2 | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV56776488; called by muse, mutect2, varscan2
- CMTR1 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.218); catalogued as COSV65092000; called by muse, mutect2, varscan2
- CNGB3 | c.2056G>A p.A686T | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.044); catalogued as COSV60700348; called by muse, varscan2
- CNNM2 | c.2126C>T p.A709V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV64002875; called by mutect2, varscan2
- CNPPD1 | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 72/154 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV56089232; called by mutect2, varscan2
- CNTN4 | c.2690G>A p.R897Q | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs1393573209, COSV61867862; called by mutect2, varscan2
- CNTN6 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV63167352; called by muse, mutect2, varscan2
- CNTNAP2 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 16/77 reads (21%) | catalogued as COSV62225013, COSV62272373; called by mutect2, varscan2
- CNTNAP2 | c.1684C>T p.H562Y | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs749273471, COSV62220787; called by mutect2, varscan2
- CNTNAP2 | c.3709G>A p.D1237N | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.43); PolyPhen benign (0.052); catalogued as rs796052386, CD061392, COSV62272378; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP2 | c.3941A>G p.N1314S | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.045); catalogued as rs747060975, COSV62272382; called by muse, mutect2, varscan2
- CNTNAP3 | c.3431G>A p.G1144E | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52666640; called by muse, mutect2, varscan2
- COL10A1 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs766938257, COSV54575192; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL11A2 | c.3809G>A p.G1270D (on ENST00000341947 / NM_080680.3; = p.G1163D on NM_080679.2) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59503256, COSV59504061; called by muse, mutect2, varscan2
- COL11A2 | c.1316C>T p.S439L (on ENST00000341947 / NM_080680.3; = p.S332L on NM_080679.2) | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.9); catalogued as COSV59504068; called by mutect2, varscan2
- COL14A1 | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.994); catalogued as COSV52848515, COSV52871932; called by muse, varscan2
- COL14A1 | c.3919G>A p.E1307K | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52847444; called by muse, varscan2
- COL15A1 | c.4018G>A p.E1340K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV66642823; called by mutect2, varscan2
- COL18A1 | c.3332G>A p.G1111E (on ENST00000359759 / NM_130444.3; = p.G876E on NM_030582.4) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60594636; called by mutect2, varscan2
- COL19A1 | c.2732G>A p.G911E | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59567516, COSV59571703; called by mutect2, varscan2
- COL21A1 | c.1628C>T p.S543L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs771765654, COSV55156257; called by mutect2, varscan2
- COL21A1 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368730001; called by mutect2, varscan2
- COL22A1 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 50/240 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV57332908; called by muse, varscan2
- COL23A1 | c.542G>A p.G181E | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746848911, COSV66800622; called by mutect2, varscan2
- COL24A1 | c.1868C>T p.P623L | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV65316487; called by muse, mutect2, varscan2
- COL28A1 | c.1418G>A p.G473E | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68082607; called by muse, varscan2
- COL28A1 | c.839G>A p.G280E | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68085432; called by muse, mutect2, varscan2
- COL3A1 | c.2797G>A p.G933R | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM119026, COSV58598341; called by muse, mutect2, varscan2
- COL4A4 | c.2681G>A p.G894E | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61637614; called by muse, mutect2, varscan2
- COL4A4 | c.2158C>T p.P720S | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs1282108781, COSV61632717, COSV61637618; called by muse, mutect2, varscan2
- COL4A6 | c.4622A>T p.K1541I | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57881563; called by mutect2, varscan2
- COL4A6 | c.2222C>T p.P741L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as COSV57881587; called by muse, mutect2, varscan2
- COL5A1 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.25); PolyPhen benign (0.105); catalogued as rs777789161, COSV65676491; called by mutect2, varscan2
- COL6A6 | c.2149G>A p.G717S | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs751917845, COSV62040423; called by muse, mutect2, varscan2
- COL8A1 | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53729614; called by muse, mutect2, varscan2
- COL9A1 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57895499; called by muse, mutect2, varscan2
- COLGALT2 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.284); catalogued as COSV62301003; called by muse, mutect2, varscan2
- COMMD1 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.156); catalogued as COSV61281794; called by mutect2, varscan2
- COPS2 | c.200G>A p.W67* | Nonsense Mutation (SNP) | VAF 11/79 reads (14%) | catalogued as COSV54648144; called by muse, mutect2, varscan2
- CORIN | c.493A>T p.N165Y | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.879); catalogued as COSV56701451; called by mutect2, varscan2
- CORO1B | c.1412G>T p.G471V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV100396628; called by mutect2, varscan2
- CORO1B | c.1411G>A p.G471S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV100396630; called by mutect2, varscan2
- CPAMD8 | c.1267G>A p.A423T (on ENST00000651564; = p.A376T on NM_015692.5) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1366662596, COSV52241565; called by mutect2, varscan2
- CPB1 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV51573676; called by muse, mutect2, varscan2
- CPD | c.2788C>T p.L930F | Missense Mutation (SNP) | VAF 58/84 reads (69%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.543); catalogued as COSV56717118; called by muse, varscan2
- CPN1 | c.567G>A p.W189* | Nonsense Mutation (SNP) | VAF 19/84 reads (23%) | catalogued as rs372009412; called by muse, mutect2, varscan2
- CPNE3 | c.689A>G p.Q230R | Missense Mutation (SNP) | VAF 88/289 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV52211596; called by muse, mutect2, varscan2
- CPNE4 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV70192770, COSV70201760; called by muse, mutect2, varscan2
- CPNE9 | c.1060G>A p.G354S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56070271; called by muse, varscan2
- CPXM2 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs751380071, COSV53872919; called by mutect2, varscan2
- CR1 | c.5129C>T p.S1710F | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.851); catalogued as COSV65465005; called by muse, varscan2
- CRACDL | c.2711G>A p.G904E | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV67410555; called by muse, varscan2
- CRAMP1 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); catalogued as COSV51967110; called by mutect2, varscan2
- CRPPA | c.1207G>A p.E403K (on ENST00000407010 / NM_001368197.1; = p.E353K on NM_001101417.4) | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67908600, COSV67909485; called by muse, varscan2
- CRYGC | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.363); catalogued as rs745713563, COSV52206334; called by mutect2, varscan2
- CSGALNACT1 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.261); catalogued as rs771457349, COSV59984708; called by muse, varscan2
- CSMD1 | c.7856G>A p.R2619Q (on ENST00000520002; = p.R2618Q on NM_033225.6) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs756592339, COSV100152479, COSV59380103; called by mutect2, varscan2
- CSMD1 | c.6832G>A p.E2278K (on ENST00000520002; = p.E2277K on NM_033225.6) | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.988); catalogued as rs763832031, COSV59383429; called by mutect2, varscan2
- CSMD1 | c.3921G>T p.W1307C (on ENST00000520002; = p.W1306C on NM_033225.6) | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV100150276, COSV100151127; called by muse, mutect2, varscan2
- CSMD1 | c.3229C>T p.R1077C (on ENST00000520002; = p.R1076C on NM_033225.6) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867742507, COSV59279573, COSV59288383; called by mutect2, varscan2
- CSMD1 | c.461G>A p.G154E | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs752648515, COSV68271917; called by muse, varscan2
- CSMD1 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV101217377; called by muse, varscan2
- CSMD3 | c.9725G>A p.G3242E (on ENST00000297405 / NM_001363185.1; = p.G3073E on NM_052900.3) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52108969; called by mutect2, varscan2
- CSMD3 | c.7841C>T p.S2614F (on ENST00000297405 / NM_001363185.1; = p.S2510F on NM_052900.3) | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV52125917; called by mutect2, varscan2
- CSMD3 | c.7550-1G>A p.X2517_splice (on ENST00000297405 / NM_001363185.1; = p.X2413_splice on NM_052900.3) | Splice Site (SNP) | VAF 9/100 reads (9%) | catalogued as COSV52183110, COSV52351376; called by muse, mutect2
- CSMD3 | c.6046C>T p.H2016Y (on ENST00000297405 / NM_001363185.1; = p.H1912Y on NM_052900.3) | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as COSV99838741; called by muse, varscan2
- CSMD3 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.996); catalogued as COSV52259132; called by muse, mutect2
- CSPP1 | c.724C>T p.P242S (on ENST00000676605; = p.P201S on NM_024790.6) | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.61); catalogued as COSV51594213; called by muse, mutect2, varscan2
- CST11 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65441294; called by muse, mutect2, varscan2
- CTAGE1 | c.2065C>T p.P689S | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.275); catalogued as rs758325773, COSV101194592; called by muse, mutect2, varscan2
- CTAGE1 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 33/270 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV66942938, COSV66945408; called by muse, mutect2, varscan2
- CTNNA2 | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.861); catalogued as COSV58160028; called by mutect2, varscan2
- CTNNB1 | c.2141C>T p.P714L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.075); catalogued as COSV100846291, COSV62705613; called by muse, mutect2, varscan2
- CTNND1 | c.2653C>T p.R885W | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs369783710; called by mutect2, varscan2
- CUBN | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.062); catalogued as COSV64729978; called by muse, mutect2, varscan2
- CUL2 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV101039206; called by muse, mutect2, varscan2
- CUX2 | c.232C>T p.L78F | Missense Mutation (SNP) | VAF 54/274 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55651340; called by muse, mutect2, varscan2
- CUZD1 | c.858A>G p.I286M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV59028656; called by muse, mutect2, varscan2
- CWF19L2 | c.1642C>T p.L548F | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1280738478, COSV56509524; called by muse, mutect2, varscan2
- CWH43 | c.2004A>T p.K668N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV56945038; called by mutect2, varscan2
- CWH43 | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.269); catalogued as COSV56937070; called by mutect2, varscan2
- CXorf66 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 73/281 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.09); catalogued as COSV65169461; called by muse, mutect2, varscan2
- CYB5R4 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1323915508, COSV63747543; called by muse, mutect2, varscan2
- CYFIP2 | c.1368G>A p.M456I | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV100557293; called by mutect2, varscan2
- CYFIP2 | c.3298C>T p.R1100C (on ENST00000616178 / NM_001291722.2; = p.R1075C on NM_014376.4) | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs868315333, COSV59054035; called by mutect2, varscan2
- CYLC1 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV61416789; called by mutect2, varscan2
- CYLD | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs751380834, COSV61097978; called by mutect2, varscan2
- CYP2C19 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64907269; called by muse, mutect2, varscan2
- CYP2C19 | c.1130G>A p.R377K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as COSV64909865; called by muse, mutect2, varscan2
- CYP2C9 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53246736; called by muse, mutect2, varscan2
- CYP3A7 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV60483782; called by muse, varscan2
- CYP4F11 | c.359A>G p.K120R | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99930945; called by muse, mutect2, varscan2
- CYP4Z1 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs868399298, COSV61964879; called by muse, mutect2, varscan2
- DAB1 | c.1141C>T p.P381S (on ENST00000371231; = p.P348S on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1354818384, COSV64689728; called by muse, mutect2, varscan2
- DACH1 | c.1834C>T p.P612S (on ENST00000619232 / NM_001366712.1; = p.P358S on NM_004392.6) | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV57490296; called by muse, mutect2, varscan2
- DCAF8L1 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as COSV71595582; called by mutect2, varscan2
- DCC | c.3393G>A p.K1131= | Splice Region (SNP) | VAF 28/42 reads (67%) | catalogued as COSV71427284; called by muse, mutect2, varscan2
- DCDC1 | c.2987G>A p.R996K (on ENST00000597505 / NM_001367979.1; = p.R103K on NM_020869.3) | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV60308111, COSV60312886; called by muse, mutect2, varscan2
- DCLK3 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV69365184; called by muse, mutect2, varscan2
- DCLRE1C | c.950C>T p.S317F (on ENST00000378278 / NM_001350965.2; = p.S202F on NM_022487.4) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as COSV63186168; called by muse, mutect2, varscan2
- DCN | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV50010079; called by muse, mutect2, varscan2
- DCN | c.353G>A p.S118N | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs1337382086, COSV99272405; called by muse, mutect2, varscan2
- DDAH2 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 48/299 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as COSV65384551; called by muse, mutect2, varscan2
- DDB1 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as COSV57106959; called by muse, mutect2, varscan2
- DDI1 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.285); catalogued as COSV56396874; called by muse, mutect2, varscan2
- DDI1 | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV56389833; called by mutect2, varscan2
- DDN | c.2080C>T p.L694F | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as COSV101373608, COSV70405492; called by muse, mutect2, varscan2
- DDO | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as rs371549796; called by mutect2, varscan2
- DDR1 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61327151; called by muse, mutect2, varscan2
- DDX27 | c.1032C>G p.I344M | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV65629737, COSV65631187; called by mutect2, varscan2
- DDX31 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV60140464; called by mutect2, varscan2
- DDX39B | c.952C>T p.H318Y | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV66020675; called by muse, mutect2, varscan2
- DDX43 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV64812609; called by mutect2, varscan2
- DDX49 | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV99447645; called by mutect2, varscan2
- DDX49 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as COSV99447650; called by muse, mutect2, varscan2
- DENR | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.449); catalogued as COSV99757387; called by mutect2, varscan2
- DEUP1 | c.1621G>A p.D541N | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV53217750; called by mutect2, varscan2
- DGCR8 | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.224); catalogued as rs1432494752, COSV100708054; called by muse, mutect2, varscan2
- DGKD | c.2719C>T p.L907F (on ENST00000264057 / NM_152879.3; = p.L863F on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.464); catalogued as COSV51121750, COSV99896082; called by muse, mutect2, varscan2
- DGKH | c.2459C>T p.S820L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as rs781029886, COSV54943912; called by mutect2, varscan2
- DGKK | c.1848G>A p.W616* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV65709098, COSV65709716; called by muse, mutect2, varscan2
- DHRSX | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58140375; called by muse, mutect2, varscan2
- DICER1 | c.2210C>T p.P737L | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV58630103; called by muse, mutect2, varscan2
- DIMT1 | c.623G>A p.R208K | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.834); catalogued as rs770284708, COSV52235295; called by muse, mutect2, varscan2
- DIS3 | c.887T>C p.L296P | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV66708359; called by muse, mutect2, varscan2
- DLEC1 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs375728827; called by mutect2, varscan2
- DLG4 | c.1955C>T p.P652L (on ENST00000399506 / NM_001321075.3; = p.P695L on NM_001365.4) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV57242761; called by muse, mutect2, varscan2
- DMBT1 | c.2351G>A p.G784E | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs1202998169, COSV57566645; called by muse, mutect2, varscan2
- DMBT1 | c.3055G>A p.D1019N (on ENST00000338354 / NM_001377530.1; = p.D520N on NM_004406.3) | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as rs773492969, COSV57545842; called by mutect2, varscan2
- DMD | c.7441G>A p.E2481K | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CD165368, COSV58960433; called by muse, varscan2
- DMRTB1 | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs748303555, COSV65114245; called by mutect2, varscan2
- DMXL1 | c.3655T>G p.L1219V | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV60723205; called by muse, mutect2, varscan2
- DNAH11 | c.3214A>G p.I1072V | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV60987725; called by muse, mutect2, varscan2
- DNAH11 | c.6236C>T p.S2079F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV60951620, COSV60987755; called by muse, mutect2, varscan2
- DNAH11 | c.10687G>A p.G3563R | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100179712; called by muse, varscan2
- DNAH11 | c.10926T>G p.F3642L | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV60987791; called by muse, varscan2
- DNAH2 | c.6644C>T p.S2215F | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66723225; called by muse, mutect2, varscan2
- DNAH3 | c.10133C>T p.T3378I | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as rs150659278; called by muse, mutect2, varscan2
- DNAH3 | c.9800A>G p.K3267R | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54559480; called by muse, mutect2, varscan2
- DNAH3 | c.3415C>T p.Q1139* | Nonsense Mutation (SNP) | VAF 15/106 reads (14%) | catalogued as COSV54559501; called by muse, mutect2, varscan2
- DNAH5 | c.11275G>A p.E3759K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs1349417589, COSV54243331; called by muse, varscan2
- DNAH5 | c.5297C>T p.S1766F | Missense Mutation (SNP) | VAF 56/96 reads (58%) | SIFT tolerated (0.71); PolyPhen benign (0.02); catalogued as COSV54224682; called by muse, mutect2, varscan2
- DNAH5 | c.4806G>A p.M1602I | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs759925845, COSV99451386; called by mutect2, varscan2
- DNAH5 | c.3544G>A p.E1182K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs868077328, COSV54224694; called by mutect2, varscan2
- DNAH6 | c.1486-1G>A p.X496_splice | Splice Site (SNP) | VAF 13/54 reads (24%) | catalogued as COSV99407464; called by muse, mutect2, varscan2
- DNAH7 | c.8518G>A p.E2840K | Missense Mutation (SNP) | VAF 31/233 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV56753749; called by muse, mutect2, varscan2
- DNAH7 | c.5860G>A p.D1954N | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as COSV56791533; called by muse, mutect2, varscan2
- DNAH7 | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.714); catalogued as rs769106832, COSV56764893; called by muse, mutect2, varscan2
- DNAH7 | c.16-1G>A p.X6_splice | Splice Site (SNP) | VAF 22/124 reads (18%) | catalogued as COSV56791572; called by muse, varscan2
- DNAH8 | c.5579G>A p.G1860E | Missense Mutation (SNP) | VAF 74/152 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs989332520, COSV59477165; called by muse, varscan2
- DNAH8 | c.12221C>T p.P4074L | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59487047; called by muse, varscan2
- DNAH9 | c.3412G>A p.E1138K | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs866851408, COSV52343092; called by mutect2, varscan2
- DNAH9 | c.5151G>A p.Q1717= | Splice Region (SNP) | VAF 8/48 reads (17%) | catalogued as rs55888525, COSV52382623; called by mutect2, varscan2
- DNAJB2 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as COSV60676285, COSV60678066; called by muse, mutect2, varscan2
- DNAJC10 | c.2143A>T p.R715W | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV51149609; called by mutect2, varscan2
- DNAJC5B | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs538469889, COSV52541223; called by muse, mutect2, varscan2
- DNTT | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64523867; called by muse, varscan2
- DOCK1 | c.4762G>A p.E1588K | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as COSV54764993; called by muse, mutect2, varscan2
- DOCK3 | c.5258C>T p.S1753F | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as COSV56555509; called by mutect2, varscan2
- DOCK3 | c.5602C>T p.P1868S | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.994); catalogued as COSV56555524; called by muse, mutect2, varscan2
- DOP1B | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67697087; called by muse, mutect2, varscan2
- DPPA2 | c.120G>A p.M40I | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs368412698; called by muse, varscan2
- DPRX | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 14/58 reads (24%) | catalogued as rs150237904; called by mutect2, varscan2
- DPY19L1 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60584968; called by muse, mutect2, varscan2
- DPYD | c.2384G>A p.G795E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64594494; called by mutect2, varscan2
- DPYD | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV64619096; called by muse, mutect2, varscan2
- DRD1 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV101192501, COSV67105346; called by mutect2, varscan2
- DSC3 | c.463T>A p.F155I | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.385); catalogued as COSV64575985; called by muse, mutect2, varscan2
- DSCAM | c.5963C>T p.S1988F | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV68025396; called by mutect2, varscan2
- DSCAM | c.839T>A p.I280N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV68038792; called by muse, varscan2
- DSCAML1 | c.4870G>A p.A1624T (on ENST00000321322; = p.A1564T on NM_020693.4) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV58405443; called by muse, mutect2, varscan2
- DSCAML1 | c.3593-1G>A p.X1198_splice (on ENST00000321322; = p.X1138_splice on NM_020693.4) | Splice Site (SNP) | VAF 7/55 reads (13%) | catalogued as COSV58405449; called by muse, mutect2, varscan2
- DSG1 | c.1385G>A p.G462E | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs148956893, COSV57136497; called by mutect2, varscan2
- DSG1 | c.2039C>T p.S680F | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV57139794, COSV57140282; called by muse, mutect2, varscan2
- DSG3 | c.1838C>T p.S613L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV57129201; called by muse, mutect2, varscan2
- DSG3 | c.2157G>A p.M719I | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1395179723, COSV57126108; called by muse, mutect2, varscan2
- DSP | c.2010G>A p.M670I | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV65796943; called by muse, mutect2, varscan2
- DSPP | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.028); catalogued as COSV56808473; called by muse, varscan2
- DUSP10 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs770815036, COSV60457708; called by mutect2, varscan2
- DYDC1 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.518); catalogued as COSV64732297; called by muse, varscan2
- DYNC1H1 | c.2681C>T p.S894F | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs267603881, COSV64140484; called by muse, mutect2, varscan2
- E2F8 | c.2003G>A p.R668K | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51464574; called by muse, mutect2, varscan2
- E2F8 | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV51466704; called by muse, mutect2, varscan2
- E2F8 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs372105528; called by mutect2, varscan2
- EBF2 | c.1543C>T p.P515S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.611); catalogued as COSV68781088; called by muse, mutect2, varscan2
- ECT2 | c.364C>T p.P122S (on ENST00000392692 / NM_001349098.2; = p.P91S on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/211 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV51690873, COSV99221529; called by muse, mutect2, varscan2
- ECT2 | c.365C>T p.P122L (on ENST00000392692 / NM_001349098.2; = p.P91L on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs760097132, COSV51695979; called by mutect2, varscan2
- EDN2 | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65423721; called by muse, mutect2, varscan2
- EEFSEC | c.661T>G p.S221A | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV54634618; called by muse, mutect2, varscan2
- EFCAB1 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50620507; called by muse, mutect2
- EFHB | c.2263C>T p.P755S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV55550576; called by mutect2, varscan2
- EFL1 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs376672172; called by mutect2, varscan2
- EFR3A | c.655T>C p.S219P | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs766690879, COSV54463576; called by muse, mutect2, varscan2
- EGFLAM | c.2593T>C p.F865L (on ENST00000354891 / NM_001205301.2; = p.F857L on NM_152403.4) | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV59320853; called by muse, mutect2, varscan2
- EHD3 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs138474287; called by muse, varscan2
- EHHADH | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs776874092, COSV51628497; ClinVar: uncertain significance; called by mutect2, varscan2
- EIF3G | c.293G>A p.R98K | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV53460771, COSV99463051; called by muse, varscan2
- EIF4E3 | c.436A>G p.T146A (on ENST00000425534 / NM_001134651.2; = p.T40A on NM_173359.5) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.066); catalogued as rs770093039, COSV55207672; called by muse, mutect2
- ELAPOR2 | c.3031G>A p.E1011K (on ENST00000450689 / NM_001142749.3; = p.E844K on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as COSV51884232, COSV51888478; called by muse, mutect2, varscan2
- ELAVL2 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1563970615, COSV56359348; called by mutect2, varscan2
- ELMO1 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.182); catalogued as COSV60294929; called by muse, varscan2
- ELOC | c.184T>A p.F62I | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV53024360; called by mutect2, varscan2
- EMC4 | c.522G>A p.M174I | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV50784963; called by muse, mutect2, varscan2
- EMD | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as rs782412064, COSV63962571; called by muse, mutect2, varscan2
- EMILIN2 | c.321G>A p.W107* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as COSV54428623; called by muse, mutect2, varscan2
- EML4 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as rs201901757, COSV59306656; called by muse, mutect2, varscan2
- EMSY | c.3022C>T p.Q1008* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as COSV100595810; called by mutect2, varscan2
- ENAM | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV68536863; called by mutect2, varscan2
- ENPP1 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62937378; called by muse, mutect2, varscan2
- ENPP1 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62937387; called by mutect2, varscan2
- ENPP3 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.732); catalogued as COSV62957462; called by muse, mutect2, varscan2
- EP400 | c.4457C>T p.A1486V | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.005); catalogued as COSV57789382; called by muse, varscan2
- EPB42 | c.999G>A p.W333* (on ENST00000441366 / NM_001114134.2; = p.W363* on NM_000119.3) | Nonsense Mutation (SNP) | VAF 3/26 reads (12%) | catalogued as rs201351228, COSV55752476; called by mutect2, varscan2
- EPHA6 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67557029, COSV67575552; called by muse, varscan2
- EPHA6 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV67559487; called by muse, varscan2
- EPHA7 | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65169784, COSV65170145; called by muse, mutect2, varscan2
- EPHB1 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.984); catalogued as rs752494038, COSV67660520; called by muse, mutect2, varscan2
- EPHB1 | c.2286C>A p.D762E | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV67674165; called by mutect2, varscan2
- EPS8L3 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1242280872, COSV62610880; called by muse, mutect2
- EPYC | c.775A>T p.N259Y | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV53802667; called by mutect2, varscan2
- ERBB3 | c.1738C>T p.R580* | Nonsense Mutation (SNP) | VAF 22/83 reads (27%) | catalogued as rs371577741, COSV57265131; called by muse, mutect2, varscan2
- ERC2 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as rs866429245, COSV55642982; called by mutect2, varscan2
- ERG | c.1225C>T p.H409Y (on ENST00000398919 / NM_001243428.1; = p.H385Y on NM_004449.4) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV55740835; called by muse, varscan2
- ERI1 | c.712T>C p.F238L | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV51573008; called by muse, mutect2, varscan2
- ERICH3 | c.3542G>A p.R1181K | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as rs1453501587, COSV58602835, COSV58621763; called by muse, mutect2, varscan2
- ERMARD | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV64652041; called by muse, mutect2, varscan2
- ERMP1 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as rs751332099, COSV53039962; called by mutect2, varscan2
- ERN2 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768486434, COSV56838733; called by mutect2, varscan2
- ERV3-1 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs1356542926, COSV51428347; called by mutect2, varscan2
- ESRRG | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV63185595; called by muse, mutect2, varscan2
- ESYT3 | c.2339A>G p.N780S | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV67442403; called by muse, mutect2, varscan2
- ETV4 | c.752G>A p.R251K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV60045764; called by muse, varscan2
- ETV6 | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1465114480, COSV67149150; called by mutect2, varscan2
- EXD1 | c.691-1G>A p.X231_splice | Splice Site (SNP) | VAF 41/73 reads (56%) | catalogued as COSV59257053; called by muse, mutect2, varscan2
- EXOC4 | c.410T>C p.V137A | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV54128032; called by muse, mutect2, varscan2
- EXPH5 | c.4756G>A p.E1586K | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56200359; called by muse, mutect2, varscan2
- EYA1 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.526); catalogued as COSV58176505; called by muse, mutect2, varscan2
- EZR | c.1274C>T p.T425I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.61); catalogued as COSV99792159; called by muse, mutect2, varscan2
- F2 | c.1495G>A p.G499R | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61314812; called by muse, mutect2, varscan2
- F5 | c.3200C>T p.S1067L | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.758); catalogued as rs866332448, COSV63124248; called by mutect2, varscan2
- F5 | c.2536G>A p.G846R | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.243); catalogued as COSV63129643; called by muse, varscan2
- F5 | c.2389G>A p.A797T | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63129649; called by muse, varscan2
- FAAH | c.1582G>A p.G528R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.149); catalogued as COSV54546500; called by mutect2, varscan2
- FABP12 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 36/360 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64617779; called by muse, mutect2
- FAM111A | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV64655697; called by muse, mutect2, varscan2
- FAM114A2 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.053); catalogued as COSV59458074; called by mutect2, varscan2
- FAM135B | c.3449-1G>A p.X1150_splice | Splice Site (SNP) | VAF 11/78 reads (14%) | catalogued as COSV52759047; called by muse, mutect2, varscan2
- FAM153B | c.469C>T p.H157Y (on ENST00000253490; = p.H80Y on NM_001265615.1) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.123); catalogued as COSV99498718; called by mutect2, varscan2
- FAM170A | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.801); catalogued as COSV58927658, COSV58927824; called by muse, mutect2, varscan2
- FAM171A1 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65321047, COSV99070850; called by mutect2, varscan2
- FAM193A | c.1999C>T p.P667S | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.301); catalogued as rs777709500, COSV61199833; called by muse, varscan2
- FAM47A | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60500526; called by muse, mutect2, varscan2
- FAM83B | c.571A>G p.M191V | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60928072; called by muse, mutect2, varscan2
- FAM83F | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV100329107, COSV61001840; called by muse, mutect2, varscan2
- FAP | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs747747073, COSV51861339; called by mutect2, varscan2
- FASN | c.1957G>A p.G653R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100148014; called by muse, varscan2
- FASTKD2 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.062); catalogued as COSV99379081; called by mutect2, varscan2
- FAT1 | c.2228A>T p.D743V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71676391; called by muse, mutect2, varscan2
- FAT2 | c.10483G>A p.E3495K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.912); catalogued as COSV55832067; called by muse, mutect2, varscan2
- FAT3 | c.189C>G p.N63K | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.025); catalogued as COSV53188699; called by muse, mutect2, varscan2
- FAT3 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV53113691; called by muse, mutect2, varscan2
- FAT3 | c.9386C>T p.P3129L | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53077487, COSV53188735; called by muse, mutect2, varscan2
- FAT3 | c.10330C>T p.P3444S | Missense Mutation (SNP) | VAF 64/300 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV53188751; called by muse, varscan2
- FAT4 | c.5344G>A p.G1782R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58714005; called by muse, mutect2, varscan2
- FAT4 | c.6647C>A p.P2216H | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.736); catalogued as COSV58695941; called by muse, varscan2
- FAT4 | c.13433G>A p.G4478E | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV100629147; called by mutect2, varscan2
- FBN3 | c.4553C>T p.S1518F | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54476113; called by muse, varscan2
- FBN3 | c.4232G>A p.G1411E | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV99561303; called by muse, mutect2, varscan2
- FBN3 | c.4231G>A p.G1411R | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.046); catalogued as COSV99561307; called by muse, mutect2, varscan2
- FBXO15 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as rs758205246, COSV54047043; called by muse, mutect2, varscan2
- FBXO34 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as rs1024306267, COSV58257656; called by mutect2, varscan2
- FBXO46 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.79); PolyPhen benign (0.015); catalogued as rs1158753956, COSV100480262; called by mutect2, varscan2
- FBXW11 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as rs1042294820, COSV51614819; called by mutect2, varscan2
- FCGBP | c.2194G>A p.V732I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.02); catalogued as rs1449613085; called by mutect2, varscan2
- FCRL4 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV54864083; called by muse, mutect2, varscan2
- FCRL5 | c.2381G>A p.G794E | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.406); catalogued as COSV100709441, COSV62521502; called by muse, mutect2, varscan2
- FCRLA | c.1057G>A p.D353N (on ENST00000367959; = p.D330N on NM_032738.4) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.722); catalogued as COSV52684129, COSV52686878; called by muse, mutect2, varscan2
- FER1L6 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV67548784; called by muse, mutect2
- FER1L6 | c.1337G>A p.G446E | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV67553432; called by muse, mutect2, varscan2
- FER1L6 | c.2798C>T p.P933L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV101205329; called by mutect2, varscan2
- FEZF1 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58659971; called by muse, varscan2
- FEZF2 | c.1124A>G p.N375S | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV51863994; called by muse, mutect2, varscan2
- FGF13 | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.269); catalogued as COSV59547637; called by muse, varscan2
- FGF13 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV59551534; called by muse, varscan2
- FGF14 | c.482T>G p.L161W | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65961079; called by muse, mutect2, varscan2
- FGFR2 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.397); catalogued as COSV60641020; called by muse, mutect2, varscan2
- FGG | c.1286G>A p.G429E | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as rs758530530, COSV60197123; called by muse, mutect2, varscan2
- FH | c.904+2T>G p.X302_splice | Splice Site (SNP) | VAF 9/82 reads (11%) | catalogued as COSV63819190; called by muse, mutect2, varscan2
- FHOD3 | c.3760C>T p.R1254C (on ENST00000359247 / NM_001281739.3; = p.R1271C on NM_025135.5) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV57191467; called by mutect2, varscan2
- FILIP1 | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV52743247; called by muse, mutect2, varscan2
- FILIP1L | c.2627G>A p.G876E (on ENST00000354552 / NM_182909.3; = p.G636E on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1197919343, COSV58765591; called by muse, mutect2, varscan2
- FIP1L1 | c.639C>A p.A213= | Splice Region (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100184537; called by mutect2, varscan2
- FIZ1 | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV55609600; called by mutect2, varscan2
- FKBPL | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 34/336 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.286); catalogued as rs368026293; called by mutect2, varscan2
- FLG | c.11105G>A p.G3702E | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs1274174043, COSV64253384; called by muse, mutect2, varscan2
- FLG | c.6146G>A p.G2049E | Missense Mutation (SNP) | VAF 38/301 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); catalogued as rs1297450677, COSV64252007; called by muse, mutect2, varscan2
- FLG | c.3872C>T p.S1291F | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV64252013; called by muse, mutect2, varscan2
- FLG | c.1829G>A p.G610E | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs200858156, COSV64243479; called by muse, mutect2, varscan2
- FLG2 | c.6164G>A p.G2055E | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.825); catalogued as rs200175088, COSV66174575; called by muse, mutect2, varscan2
- FLG2 | c.5101G>A p.D1701N | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV66174580; called by muse, mutect2, varscan2
- FLG2 | c.3803G>A p.R1268Q | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as rs755946938, COSV66166962; called by mutect2, varscan2
- FLNB | c.4682G>A p.G1561E | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55899801; called by mutect2, varscan2
- FLOT1 | c.571-1G>A p.X191_splice | Splice Site (SNP) | VAF 8/90 reads (9%) | catalogued as COSV52544758; called by muse, mutect2
- FLRT2 | c.1793C>T p.S598F | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58152217; called by muse, varscan2
- FLT4 | c.3410C>T p.P1137L | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM032233, COSV56101603; called by muse, mutect2, varscan2
- FNDC3A | c.397C>T p.P133S (on ENST00000492622 / NM_001079673.2; = p.P77S on NM_014923.5) | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.226); catalogued as COSV101001304; called by muse, mutect2, varscan2
- FNDC4 | c.619G>A p.G207R | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV99253955; called by muse, mutect2, varscan2
- FNIP1 | c.2953G>A p.E985K | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); catalogued as COSV57194262; called by mutect2, varscan2
- FOSB | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.422); catalogued as COSV62278420; called by mutect2, varscan2
- FOXK2 | c.967C>T p.Q323* | Nonsense Mutation (SNP) | VAF 26/64 reads (41%) | catalogued as COSV58883768; called by muse, varscan2
- FOXP2 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as rs759256511, COSV63495586; ClinVar: uncertain significance; called by mutect2, varscan2
- FOXS1 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.665); catalogued as rs757397108, COSV54067232; called by mutect2, varscan2
- FREM1 | c.5533G>A p.V1845M | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV66532055; called by muse, mutect2, varscan2
- FREM1 | c.3601T>C p.F1201L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV66532064; called by muse, mutect2, varscan2
- FRG2B | c.97G>A p.G33S | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.439); catalogued as rs767666386, COSV71044085; called by mutect2, varscan2
- FRMD3 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58472319; called by muse, varscan2
- FRMD4A | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99198563; called by muse, mutect2, varscan2
- FRMPD4 | c.3851G>A p.G1284E | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.109); catalogued as COSV66225314; called by muse, mutect2, varscan2
- FRS3 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.185); catalogued as rs1263897930, COSV52487343; called by muse, mutect2, varscan2
- FRYL | c.7311T>G p.D2437E | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV51965252; called by muse, mutect2, varscan2
- FRYL | c.1085T>C p.L362S | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51965261; called by muse, mutect2, varscan2
- FTHL17 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV63266373; called by mutect2, varscan2
- FTO | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67114934; called by muse, varscan2
- FURIN | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.101); catalogued as rs1222789876, COSV51580400; called by muse, mutect2, varscan2
- FYB2 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs1314179707, COSV100599695, COSV58590304; called by muse, mutect2, varscan2
- FYCO1 | c.959A>T p.Q320L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.221); catalogued as COSV56120853; called by muse, mutect2, varscan2
- FZD2 | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.523); catalogued as rs1423453742, COSV59530605; called by mutect2, varscan2
- FZD4 | c.1488G>T p.W496C | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as CM095231, COSV72294794; called by muse, mutect2, varscan2
- GABPB2 | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV64461739; called by muse, mutect2, varscan2
- GABRA6 | c.379C>T p.H127Y | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50899867; called by mutect2, varscan2
- GABRA6 | c.423T>G p.N141K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV50899965; called by muse, mutect2, varscan2
- GABRB1 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV54971447; called by muse, mutect2, varscan2
- GABRG2 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); catalogued as rs867789510, COSV62723536; called by muse, mutect2, varscan2
- GALNT17 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as COSV61153625; called by mutect2, varscan2
- GALNT3 | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV67061411; called by muse, mutect2, varscan2
- GAR1 | c.362G>A p.R121K | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.151); catalogued as rs1344949005, COSV56994205; called by muse, mutect2, varscan2
- GAS2L2 | c.2111G>A p.R704K | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1266812912; called by muse, mutect2, varscan2
- GBA3 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as COSV72438860; called by muse, varscan2
- GBP2 | c.1073G>A p.S358N | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV65070731; called by muse, mutect2, varscan2
- GBP6 | c.1357G>A p.G453R | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65012833; called by muse, mutect2, varscan2
- GBP7 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as rs1350951524, COSV54010734; called by mutect2, varscan2
- GCOM1 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.212); catalogued as rs866578359, COSV51094729; called by mutect2, varscan2
- GDF10 | c.1262A>G p.N421S | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1240837272; called by muse, mutect2
- GDNF | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV58482583; called by muse, varscan2
- GEM | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.557); catalogued as rs1237330383, COSV52597459; called by mutect2, varscan2
- GEMIN5 | c.3890C>T p.P1297L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs756747985, COSV53562224; called by muse, mutect2, varscan2
- GFM1 | c.1022T>G p.I341S | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as COSV99962988; called by muse, mutect2, varscan2
- GFRA2 | c.1121A>C p.Q374P | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV60777819, COSV60782552; called by muse, mutect2
- GFRAL | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs532430727, COSV61233444; called by mutect2, varscan2
- GFRAL | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV61236720; called by muse, mutect2
- GID8 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs772878499, COSV56611509, COSV56611890; called by mutect2, varscan2
- GIMAP1 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.095); catalogued as rs746747085, COSV56189722, COSV56190219; called by mutect2, varscan2
- GIMAP2 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56236636; called by mutect2, varscan2
- GIMAP5 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57529987, COSV57530647; called by muse, varscan2
- GIMAP6 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.326); catalogued as COSV61034039; called by muse, mutect2
- GIMAP6 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61034350; called by muse, mutect2, varscan2
- GIMAP6 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 34/228 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs866496608, COSV61032580; called by muse, varscan2
- GIPC3 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100461397; called by muse, mutect2, varscan2
- GJA10 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs770565371, COSV65355587; called by mutect2, varscan2
- GJA8 | c.11G>A p.W4* | Nonsense Mutation (SNP) | VAF 41/90 reads (46%) | catalogued as COSV53791285; called by muse, mutect2, varscan2
- GJC1 | c.517C>T p.L173F | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57912822; called by muse, varscan2
- GJC1 | c.56T>C p.F19S | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV57912916; called by muse, mutect2, varscan2
- GK | c.1573C>T p.P525S (on ENST00000427190 / NM_001205019.2; = p.P519S on NM_000167.6) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100970363; called by muse, mutect2, varscan2
- GLB1 | c.1996C>T p.P666S | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.803); catalogued as COSV100257497; called by muse, varscan2
- GLDC | c.1769G>A p.G590E | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100394222, COSV58686490; called by muse, varscan2
- GLI2 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.065); catalogued as rs780961532, COSV58037617; called by muse, mutect2, varscan2
- GLP1R | c.79-2A>C p.X27_splice | Splice Site (SNP) | VAF 5/22 reads (23%) | catalogued as COSV64716751; called by muse, mutect2, varscan2
- GLT6D1 | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV65627665; called by muse, mutect2, varscan2
- GLT6D1 | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.534); catalogued as rs772607169, COSV100874553; called by mutect2, varscan2
- GMEB1 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV53797591; called by muse, mutect2, varscan2
- GMIP | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as rs1213104382, COSV52554047; called by muse, mutect2, varscan2
- GNA12 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1195630460, COSV51746609; called by muse, mutect2, varscan2
- GON4L | c.452C>T p.T151I | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1408890506, COSV55206859; called by muse, mutect2, varscan2
- GPNMB | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs779233817, COSV51701724; called by muse, mutect2, varscan2
- GPR101 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV53238475, COSV53240802; called by muse, mutect2, varscan2
- GPR139 | c.1037G>A p.G346E | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV58505620; called by muse, mutect2, varscan2
- GPR139 | c.170G>A p.R57K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV100429949, COSV58501556; called by muse, mutect2, varscan2
- GPR142 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV59520436; called by mutect2, varscan2
- GPR158 | c.2237C>T p.S746L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs372270249; called by mutect2, varscan2
- GPR174 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs753466887, COSV52134786; called by mutect2, varscan2
- GPR3 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1295669632, COSV64995309; called by muse, mutect2, varscan2
- GPR37 | c.541del p.Y181Tfs*65 | Frame Shift Del (DEL) | VAF 13/104 reads (13%) | catalogued as COSV58259789; called by pindel, varscan2
- GPR45 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); catalogued as COSV51526641; called by muse, mutect2, varscan2
- GPRC5C | c.1027C>T p.P343S (on ENST00000652232; = p.P298S on NM_018653.4) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61235516, COSV61235917; called by muse, mutect2, varscan2
2,481 further variants in this file (1,336 protein-altering or splice-affecting, 1,072 silent, 73 other) are not listed here.
